Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5588, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5588-01A (Primary Tumor).

[REDACTED]

[REDACTED] Surgical Pathology

[REDACTED] TCGA-CW-5588

TISSUE DESCRIPTION:

Right kidney (20 grams, 5 x 3 x 3 cm).

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forming two nodules (2.6 cm and 2.1 cm in greatest dimension), within 1 mm of the hilum. The tumor is confined to the kidney. Coagulative tumor necrosis and sarcomatoid differentiation are absent. The tumor extends to within 1 mm of the surgical margin, which is negative.

Source: NCI Genomic Data Commons file 92fdae07-6b1b-4abb-8dd1-931cce8e8420 (TCGA-CW-5588.F8F8536B-EC9C-4932-9559-D76EACE92A6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).